Somatic mutation profile of tumor specimen TARGET-10-PAPIHT-09A (aliquot TARGET-10-PAPIHT-09A-01D) from TARGET case TARGET-10-PAPIHT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (953 days).
Specimen TARGET-10-PAPIHT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f440770-0cc7-42e1-9817-9c2c6a6985b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPIHT-10A (Blood Derived Normal), aliquot TARGET-10-PAPIHT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99726edf-18c3-4807-93dd-2866b841675a

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, 3'UTR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCB5 | c.2801C>T p.A934V (on ENST00000404938 / NM_001163941.2; = p.A489V on NM_178559.6) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371459532; called by mutect2, varscan2
- CLTC | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.13); catalogued as rs764106909; called by muse, mutect2, varscan2
- DMBT1 | c.6838C>T p.L2280F (on ENST00000338354 / NM_001377530.1; = p.L1523F on NM_004406.3) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as rs1162663772, COSV57547347; called by muse, mutect2
- MATR3 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs762668138; called by muse, mutect2, varscan2
- MXRA5 | c.4481C>T p.S1494L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs764545839, COSV54232960; called by muse, mutect2, varscan2
- RGS3 | c.959G>A p.R320Q (on ENST00000350696 / NM_001282923.2; = p.R208Q on NM_017790.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58278386; called by muse, mutect2, varscan2
- EFR3B | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- MIOS | c.2445A>C p.K815N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC4A1 | c.348G>A p.K116= | Splice Region (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- SVIL | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- EIF2D | c.474G>A p.T158= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs782060879; called by muse, mutect2, varscan2
- NEBL | c.2943C>T p.I981= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs201105598; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPR2 | c.1332C>T p.D444= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs572593621, COSV61309186; called by muse, mutect2, varscan2
- SCN5A | c.2151G>A p.P717= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs191840835, COSV61133977; ClinVar: benign / likely benign / uncertain significance; called by mutect2, varscan2
- WBP2NL | c.477G>T p.G159= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- AL772337.1 | n.369C>T | RNA (SNP) | VAF 4/44 reads (9%) | catalogued as rs1046922047; called by muse, mutect2
- EDAR | c.*47C>A | 3'UTR (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
